Somatic mutation profile of tumor specimen TCGA-HT-7476-01A (aliquot TCGA-HT-7476-01A-11D-2024-08) from TCGA case TCGA-HT-7476, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 26.3 years (9,614 days).
Specimen TCGA-HT-7476-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 641f6621-5edc-4eab-ac8f-33bb34f1f0b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7476-10A (Blood Derived Normal), aliquot TCGA-HT-7476-10A-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a739991-9789-480c-82f6-dda6d362f5da

The open-access MAF lists 25 somatic variants for this specimen: 20 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 3, Nonsense Mutation 1, RNA 1, 3'Flank 1, Frame Shift Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 29/71 reads (41%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs121913503, COSV57468734, COSV57468971, COSV57472976; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 18/28 reads (64%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AP3B1 | c.989C>G p.S330C | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54891375; called by muse, mutect2, varscan2
- CDC40 | c.785G>T p.G262V | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV100309579; called by muse, mutect2
- CEP126 | c.3202A>G p.K1068E | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV54829757; called by muse, mutect2, varscan2
- COX7B | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0.03); PolyPhen benign (0.373); catalogued as COSV63782923, COSV63783312; called by muse, mutect2, varscan2
- DYNC1I1 | c.1085C>T p.S362L | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs776143490, COSV61459519; called by muse, varscan2
- ELP2 | c.1544C>T p.A515V | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV60853924; called by muse, mutect2
- FAT4 | c.2354A>G p.D785G | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV67897826; called by muse, mutect2, varscan2
- GDAP1 | c.577A>G p.K193E | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.593); catalogued as CM1411830, COSV55187017; called by muse, mutect2
- ITIH4 | c.2629C>T p.Q877* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as COSV56577963; called by muse, mutect2, varscan2
- LRFN5 | c.1171G>C p.D391H | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV53271877; called by muse, mutect2, varscan2
- MUSK | c.1690A>G p.K564E | Missense Mutation (SNP) | VAF 67/185 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51894427, COSV51899350; called by muse, mutect2, varscan2
- MYH2 | c.1670A>G p.D557G | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV55446953; called by muse, mutect2
- PCDH19 | c.1568A>G p.H523R | Missense Mutation (SNP) | VAF 44/74 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV55270048; called by muse, mutect2, varscan2
- SPAM1 | c.686A>T p.Y229F | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.078); catalogued as COSV56144485, COSV56146996; called by muse, mutect2, varscan2
- TRPC3 | c.698A>T p.D233V (on ENST00000379645 / NM_001366479.2; = p.D160V on NM_003305.2) | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53380160; called by muse, mutect2, varscan2
- UNC45A | c.1831G>C p.E611Q | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.311); catalogued as COSV67817421; called by muse, mutect2, varscan2
- ATRX | c.1400_1401del p.K467Tfs*4 | Frame Shift Del (DEL) | VAF 90/180 reads (50%) | called by mutect2, pindel, varscan2
- TPTE | c.11G>C p.S4T | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CRACD | c.3609G>A p.P1203= | Silent (SNP) | VAF 60/182 reads (33%) | catalogued as rs752747435, COSV51730095; called by muse, mutect2, varscan2
- FLRT3 | c.696G>A p.L232= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV54041639; called by muse, mutect2, varscan2
- SPICE1 | c.1950G>C p.L650= | Silent (SNP) | VAF 32/104 reads (31%) | catalogued as COSV55624202; called by muse, mutect2, varscan2
- MIR323A | n.30G>A | RNA (SNP) | VAF 52/131 reads (40%) | catalogued as rs903273613; called by muse, mutect2, varscan2
- TRPV2 | chr17:16439524 A>G | 3'Flank (SNP) | VAF 40/143 reads (28%) | called by muse, mutect2, varscan2
